Gene-level copy-number profile of tumor specimen TCGA-MJ-A68J-01A from TCGA case TCGA-MJ-A68J, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 55.0 years (20,100 days).
Specimen TCGA-MJ-A68J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.cfe71b6d-b96c-4546-bcca-997f36883444.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MJ-A68J-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/27cbf986-2d6d-42be-a10a-6120843d98f4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 527; copy number 2: 56,793; copy number 3: 2,481.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MJ-A68J-01A-11D-A306-01): tumor purity 0.66, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:97,394,154–97,420,141, 1 gene: DPYD-IT1.
- chr1:110,210,314–110,631,474, 17 genes (within-gene range 0–1): KCNC4, AL137790.2, AL137790.1, RBM15-AS1, RBM15, LAMTOR5-AS1, SLC16A4, AL355488.1, LAMTOR5, PROK1, AL358215.1, AL358215.2, AL358215.3, CYMP, CYMP-AS1, KCNA10, KCNA2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 527. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
